Somatic mutation profile of tumor specimen TCGA-EE-A2GI-06A (aliquot TCGA-EE-A2GI-06A-11D-A196-08) from TCGA case TCGA-EE-A2GI, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 41.2 years (15,065 days).
Specimen TCGA-EE-A2GI-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8dccefd4-cf63-4069-84fb-96e25b3ada78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GI-10A (Blood Derived Normal), aliquot TCGA-EE-A2GI-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71c8791b-f809-4fc0-8c30-404b4104aedc

The open-access MAF lists 1,841 somatic variants for this specimen: 1,184 protein-altering or splice-affecting, 609 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,080, Silent 609, Nonsense Mutation 70, Intron 18, Splice Site 13, 5'Flank 11, Splice Region 10, Frame Shift Del 7, RNA 6, 3'UTR 6, Frame Shift Ins 4, 3'Flank 4.

Variants (750 of 1,841; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 20/87 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, mutect2, varscan2
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 31/51 reads (61%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6715C>T p.Q2239* (on ENST00000358273 / NM_001042492.3; = p.Q2218* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 48/82 reads (59%) | catalogued as rs1131691093, CD1415208, COSV62194886; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VCP | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs121909330, CM040815, CM092553, COSV100734231, COSV62719858; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs574044306, COSV50966965; called by mutect2, varscan2
- ABCA10 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV52229117; called by muse, mutect2, varscan2
- ABCA12 | c.6828C>G p.I2276M (on ENST00000272895 / NM_173076.3; = p.I1958M on NM_015657.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV55973742; called by muse, mutect2, varscan2
- ABCA12 | c.2765C>T p.S922F (on ENST00000272895 / NM_173076.3; = p.S604F on NM_015657.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55972721; called by muse, mutect2, varscan2
- ABCA13 | c.3532G>A p.G1178S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV70042628; called by muse, mutect2, varscan2
- ABCA13 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV70026603, COSV70042630; called by muse, mutect2, varscan2
- ABCA4 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV64677458; called by muse, mutect2, varscan2
- ABCA6 | c.3408dup p.A1137Cfs*15 | Frame Shift Ins (INS) | VAF 15/49 reads (31%) | catalogued as rs765618525; called by mutect2, pindel, varscan2
- ABCC9 | c.3728C>T p.S1243L | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751402564, COSV53964356; called by muse, mutect2, varscan2
- ABHD6 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs760745964, COSV55910200; called by muse, mutect2, varscan2
- ABI3 | c.1024T>A p.S342T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.949); catalogued as COSV56801377; called by muse, mutect2
- ABRA | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as rs1284299630, COSV61733474, COSV61733981; called by muse, mutect2, varscan2
- ACD | c.335C>T p.P112L (on ENST00000620338; = p.P26L on NM_022914.3) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as COSV54670133; called by muse, mutect2, varscan2
- ACOXL | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV61330082; called by muse, mutect2, varscan2
- ACP6 | c.978-1G>A p.X326_splice | Splice Site (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100984167, COSV65077903; called by muse, mutect2, varscan2
- ACSM2B | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as COSV61657656, COSV61659796; called by muse, varscan2
- ACSS3 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54100273; called by muse, mutect2
- ACTL6B | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV50518032, COSV50518660; called by muse, mutect2, varscan2
- ACTN3 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs1028224789, COSV101557859; called by mutect2, varscan2
- ACTR3B | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55453438; called by muse, mutect2, varscan2
- ACVR1C | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV54649501; called by muse, mutect2, varscan2
- ACVRL1 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66360987; called by muse, mutect2, varscan2
- ADAM12 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs368472298; called by muse, mutect2, varscan2
- ADAM18 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55850127; called by muse, mutect2, varscan2
- ADAM18 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV55843435; called by muse, mutect2, varscan2
- ADAM21 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV50807533; called by muse, mutect2, varscan2
- ADAM21 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV50807597; called by muse, varscan2
- ADAM22 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55988984; called by muse, mutect2, varscan2
- ADAM22 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55971893; called by muse, mutect2, varscan2
- ADAM30 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 225/629 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as COSV65562121; called by muse, mutect2, varscan2
- ADAM32 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs748555532, COSV65952246; called by muse, mutect2, varscan2
- ADAM32 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs957652162, COSV65950171; called by muse, mutect2, varscan2
- ADAM33 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62936251; called by muse, varscan2
- ADAMTS18 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV51420088; called by muse, varscan2
- ADAMTS2 | c.3556C>T p.P1186S | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.058); catalogued as COSV52391384; called by muse, mutect2, varscan2
- ADAMTS2 | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV52391398; called by muse, mutect2, varscan2
- ADAMTS9 | c.3098A>G p.D1033G | Missense Mutation (SNP) | VAF 182/590 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as rs1363050148, COSV55789590; called by muse, mutect2, varscan2
- ADAMTS9 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 163/524 reads (31%) | catalogued as rs1193053630, COSV55789599; called by muse, mutect2, varscan2
- ADAMTSL4 | c.889A>T p.R297* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV55006884; called by mutect2, varscan2
- ADCY7 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs980458232, COSV54266885; called by muse, mutect2, varscan2
- ADCY8 | c.3488G>A p.G1163E | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601769, COSV53899204; called by muse, mutect2, varscan2
- ADGRB2 | c.4252C>G p.P1418A | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV57078369; called by muse, mutect2, varscan2
- ADGRF5 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51933998; called by muse, varscan2
- ADH1B | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs1230758917, COSV59298489; called by muse, mutect2, varscan2
- ADRA1D | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65241907; called by muse, mutect2
- AFAP1L2 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs1236780680, COSV58415803; called by muse, mutect2, varscan2
- AGBL1 | c.1403G>A p.W468* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as rs1346826255, COSV66871346; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by mutect2, varscan2
- AHCYL2 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61490811; called by muse, mutect2, varscan2
- AHDC1 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55942087; called by muse, mutect2, varscan2
- AKAP8 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54104763; called by muse, mutect2, varscan2
- AKAP9 | c.8510C>T p.S2837F (on ENST00000359028; = p.S2813F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV62356880; called by muse, mutect2, varscan2
- AL645922.1 | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54962376; called by muse, mutect2, varscan2
- ALDH5A1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs867032162, COSV62372820; called by muse, mutect2, varscan2
- ALLC | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52997871; called by muse, mutect2, varscan2
- ALOX15 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as rs370447055; called by muse, mutect2, varscan2
- AMDHD1 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV57139398; called by muse, mutect2, varscan2
- AMFR | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as rs369160515; called by muse, mutect2, varscan2
- AMHR2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs146554515, COSV57685269; called by muse, mutect2, varscan2
- AMPD1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866945097, COSV62418648; called by muse, mutect2, varscan2
- ANAPC1 | c.840T>A p.N280K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV61979209; called by muse, mutect2, varscan2
- ANAPC7 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV101484777, COSV71443742; called by muse, mutect2, varscan2
- ANK2 | c.5198C>T p.S1733L | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52185616; called by mutect2, varscan2
- ANK2 | c.6820C>T p.R2274C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs140258681; called by muse, mutect2, varscan2
- ANKRD1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV63310910; called by muse, mutect2, varscan2
- ANKRD27 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV100042579, COSV100043305; called by muse, mutect2, varscan2
- ANO4 | c.886C>T p.P296S (on ENST00000392977 / NM_001286615.2; = p.P261S on NM_178826.4) | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54603900; called by muse, mutect2, varscan2
- AOX1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65983758; called by muse, mutect2, varscan2
- APOB | c.4153C>T p.L1385F | Missense Mutation (SNP) | VAF 59/358 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV51950535, COSV51952445; called by muse, varscan2
- APOBEC1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs267603686, COSV57548632; called by muse, mutect2, varscan2
- ARHGAP31 | c.3599T>C p.V1200A | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51798334; called by muse, mutect2, varscan2
- ARHGAP6 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV57299032; called by muse, mutect2, varscan2
- ARHGEF15 | c.990-1G>A p.X330_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV62726361; called by muse, mutect2, varscan2
- ARHGEF15 | c.2221A>G p.T741A | Missense Mutation (SNP) | VAF 64/103 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.217); catalogued as COSV62726368; called by muse, mutect2, varscan2
- ARHGEF2 | c.376C>T p.P126S (on ENST00000361247 / NM_001162383.2; = p.P99S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58116764; called by muse, mutect2, varscan2
- ARHGEF35 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV100967774; called by mutect2, varscan2
- ARHGEF40 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.267); catalogued as COSV53883963; called by muse, mutect2, varscan2
- ARHGEF5 | c.624A>T p.E208D | Missense Mutation (SNP) | VAF 60/436 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV99283024; called by mutect2, varscan2
- ARHGEF5 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 58/451 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs761939610, COSV99283026; called by muse, mutect2, varscan2
- ARHGEF5 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.739); catalogued as rs1198095218, COSV50218203; called by mutect2, varscan2
- ARHGEF7 | c.871C>T p.Q291* (on ENST00000375741 / NM_001113511.2; = p.Q113* on NM_003899.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV54550689; called by muse, mutect2, varscan2
- ARID3C | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as rs1212837454, COSV52408943; called by muse, mutect2, varscan2
- ARMC6 | c.943G>A p.D315N (on ENST00000392336; = p.D290N on NM_033415.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs370794754; called by mutect2, varscan2
- ARMCX5 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV55766650; called by muse, mutect2, varscan2
- ARRDC3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV54366424; called by muse, mutect2, varscan2
- ARSF | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as COSV63840953; called by muse, mutect2, varscan2
- ASAP1 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs933075970, COSV63048662; called by muse, mutect2, varscan2
- ASB15 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51928838; called by muse, mutect2, varscan2
- ATG7 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV61615410; called by muse, mutect2, varscan2
- ATMIN | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV55147490; called by muse, mutect2, varscan2
- ATP2A1 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs781166858, COSV100837343; called by mutect2, varscan2
- ATP2B3 | c.2158G>A p.G720S | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782081961, COSV54859972; called by muse, mutect2, varscan2
- ATP5PB | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100867648; called by muse, mutect2, varscan2
- ATP5PB | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100867649; called by mutect2, varscan2
- ATP5PO | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs1365558661, COSV51709077; called by muse, mutect2, varscan2
- ATP6V0D2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as COSV53412881; called by muse, mutect2, varscan2
- ATP8B1 | c.1029+1G>A p.X343_splice | Splice Site (SNP) | VAF 8/13 reads (62%) | catalogued as COSV52179659; called by muse, mutect2, varscan2
- ATXN1 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV55229695; called by muse, mutect2, varscan2
- ATXN2 | c.3377C>G p.T1126R (on ENST00000550104; = p.T966R on NM_002973.4) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV66481327, COSV66485831; called by muse, mutect2, varscan2
- AXL | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs1176757863, COSV56565136; called by mutect2, varscan2
- AXL | c.1817A>C p.Q606P (on ENST00000301178 / NM_021913.5; = p.Q597P on NM_001699.6) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV56574123; called by muse, mutect2, varscan2
- BBS7 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52658026, COSV52659236; called by muse, mutect2, varscan2
- BCAT2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60274010; called by muse, mutect2, varscan2
- BCL9 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV52343451; called by muse, mutect2, varscan2
- BCL9 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52349666; called by muse, mutect2, varscan2
- BMP10 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.896); catalogued as COSV54895132; called by muse, mutect2, varscan2
- BPIFB6 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV62756570; called by muse, mutect2
- BPTF | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs765443034, COSV58835767; called by muse, mutect2, varscan2
- BRINP3 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1237194828, COSV66539691; called by muse, mutect2, varscan2
- BRWD1 | c.4774G>A p.G1592R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV60902210; called by muse, mutect2, varscan2
- BRWD1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58123591; called by muse, mutect2, varscan2
- BTBD7 | c.3047A>G p.H1016R | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58290003; called by muse, varscan2
- BTBD9 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.763); catalogued as rs1194211383, COSV58423084; called by muse, mutect2, varscan2
- BVES | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV58949788; called by muse, mutect2, varscan2
- C10orf71 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs985271678, COSV100109959, COSV60505874; called by muse, mutect2, varscan2
- C12orf42 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as COSV59390033; called by muse, mutect2, varscan2
- C12orf42 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.208); catalogued as rs1311532483, COSV59390047; called by muse, mutect2, varscan2
- C1orf127 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as rs12567143, COSV65437039; called by muse, mutect2, varscan2
- C7 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV57480202; called by muse, mutect2, varscan2
- C7orf33 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs759489205, COSV61023126, COSV61023884; called by muse, mutect2, varscan2
- C8B | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs747647469, COSV64776503; called by muse, mutect2, varscan2
- CA2 | c.269T>C p.L90S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53408193; called by muse, mutect2, varscan2
- CACNA1C | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV59765105; called by muse, mutect2, varscan2
- CACNA1C | c.3641A>G p.Y1214C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59723445; called by muse, mutect2, varscan2
- CACNA1I | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV60817657; called by muse, mutect2, varscan2
- CACNB2 | c.1580A>C p.K527T (on ENST00000324631 / NM_201596.3; = p.K472T on NM_000724.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as rs771565696, COSV56644955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG2 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV55640459; called by muse, mutect2, varscan2
- CAD | c.3618G>A p.K1206= | Splice Region (SNP) | VAF 11/61 reads (18%) | catalogued as COSV53031360; called by muse, mutect2, varscan2
- CAGE1 | c.751G>A p.E251K (on ENST00000512086; = p.E115K on NM_205864.3) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV57081471; called by muse, mutect2, varscan2
- CAMSAP3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV50358850; called by muse, mutect2, varscan2
- CAMTA1 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV57924057; called by muse, mutect2, varscan2
- CAPN12 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61014994; called by muse, mutect2, varscan2
- CASP14 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55666571; called by muse, mutect2, varscan2
- CASS4 | c.1640T>C p.L547P | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64385463; called by muse, varscan2
- CAT | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53813049; called by muse, mutect2, varscan2
- CATSPERB | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56434144; called by muse, mutect2, varscan2
- CATSPERE | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.698); catalogued as COSV63681524; called by muse, mutect2, varscan2
- CBY1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99319944; called by muse, mutect2, varscan2
- CCDC146 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV53553741; called by muse, mutect2, varscan2
- CCDC190 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV63363595; called by muse, mutect2, varscan2
- CCDC198 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV53603403; called by muse, mutect2, varscan2
- CCDC28A | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201106266, COSV60425741, COSV60425779; called by muse, mutect2, varscan2
- CCDC39 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56481826, COSV56492841; called by muse, mutect2, varscan2
- CCDC40 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66478449; called by muse, varscan2
- CCDC60 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1424751402, COSV100554523, COSV59549936; called by muse, mutect2, varscan2
- CCDC85A | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101339499, COSV68147945; called by muse, mutect2, varscan2
- CCDC85A | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101339500; called by muse, mutect2, varscan2
- CCER1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 91/426 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.362); catalogued as COSV62648528; called by muse, mutect2, varscan2
- CCNB3 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782758904, COSV52079191; called by muse, mutect2, varscan2
- CCNL2 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV68766956; called by muse, mutect2, varscan2
- CCR1 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV56122943; called by muse, mutect2, varscan2
- CD163 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.815); catalogued as COSV63136778; called by mutect2, varscan2
- CD163L1 | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58023836; called by muse, mutect2, varscan2
- CD1D | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63809963; called by muse, mutect2, varscan2
- CD36 | c.637A>G p.K213E | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.186); catalogued as rs373829578; called by muse, mutect2, varscan2
- CD86 | c.716C>T p.P239L (on ENST00000330540 / NM_175862.5; = p.P233L on NM_006889.4) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV52609984; called by muse, mutect2, varscan2
- CDC37 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55769687; called by muse, varscan2
- CDC42EP2 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54203922; called by muse, mutect2, varscan2
- CDH12 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV66443970; called by muse, mutect2, varscan2
- CDH13 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51864253; called by muse, mutect2, varscan2
- CDH15 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV57027382; called by muse, mutect2, varscan2
- CDH4 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs758983577, COSV64672793; called by muse, mutect2, varscan2
- CDH5 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV58519714; called by muse, mutect2, varscan2
- CDH6 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs752932258, COSV54065993; called by muse, mutect2, varscan2
- CDK11A | c.1732C>T p.P578S (on ENST00000378633 / NM_001313896.2; = p.P575S on NM_024011.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs183405236, COSV52308516; called by muse, mutect2, varscan2
- CDYL2 | c.615C>T p.L205= | Splice Region (SNP) | VAF 32/80 reads (40%) | catalogued as rs778308961, COSV73647607; called by muse, mutect2
- CEBPE | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as rs1455475593, COSV52830668; called by muse, mutect2, varscan2
- CELF1 | c.1073C>T p.A358V (on ENST00000358597 / NM_001376422.1; = p.A354V on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV60115292; called by muse, mutect2, varscan2
- CEP192 | c.5480A>G p.N1827S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.554); catalogued as COSV58070095; called by muse, mutect2
- CEP55 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs146596670; called by muse, mutect2, varscan2
- CERCAM | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV65711568; called by muse, mutect2, varscan2
- CES1 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV62089842; called by muse, mutect2, varscan2
- CES3 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.987); catalogued as rs771104310, COSV57595261; called by muse, mutect2, varscan2
- CFAP206 | c.1811A>G p.K604R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV65807269, COSV65810089; called by muse, mutect2, varscan2
- CFAP299 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs753964988, COSV100812241, COSV63871600; called by muse, mutect2, varscan2
- CFAP53 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV68352807; called by muse, mutect2, varscan2
- CFHR1 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57629011; called by muse, mutect2, varscan2
- CHD4 | c.4052C>T p.S1351F (on ENST00000357008 / NM_001363606.2; = p.S1364F on NM_001273.5) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901356; called by muse, mutect2, varscan2
- CHD4 | c.3163C>T p.R1055C (on ENST00000357008 / NM_001363606.2; = p.R1068C on NM_001273.5) | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894255; called by muse, mutect2, varscan2
- CHD5 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52421933; called by muse, mutect2, varscan2
- CHD6 | c.3236C>T p.P1079L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58561985; called by muse, mutect2, varscan2
- CHI3L2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1389625143, COSV63874111; called by muse, mutect2, varscan2
- CHM | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.214); catalogued as COSV63304204; called by muse, mutect2, varscan2
- CHPF2 | c.773G>A p.W258* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | catalogued as COSV50399562; called by muse, mutect2, varscan2
- CHRNA9 | c.1383G>A p.W461* | Nonsense Mutation (SNP) | VAF 57/177 reads (32%) | catalogued as COSV59575821; called by muse, mutect2, varscan2
- CHRNB4 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55718121; called by muse, mutect2, varscan2
- CHST4 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV58298270; called by muse, mutect2, varscan2
- CKAP2L | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs76184593; called by muse, mutect2, varscan2
- CLCA4 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.232); catalogued as rs764538668, COSV55368292, COSV99760242; called by muse, mutect2, varscan2
- CLCN1 | c.2822C>T p.S941F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.08); catalogued as rs769053787, COSV58374080; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLCN7 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750415617, COSV51973554, COSV99246844; called by muse, mutect2, varscan2
- CLEC10A | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs747280103, COSV54702529; called by muse, mutect2
- CLEC4C | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV63582992; called by muse, mutect2, varscan2
- CLSTN2 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71724582, COSV71724823; called by mutect2, varscan2
- CNGA1 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.061); catalogued as COSV62056712; called by muse, mutect2, varscan2
- CNOT3 | c.653A>T p.D218V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99652138; called by muse, mutect2, varscan2
- CNTN4 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV61880301; called by muse, mutect2, varscan2
- CNTNAP5 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs765130255, COSV70494484; called by muse, mutect2, varscan2
- COL12A1 | c.9070G>A p.G3024S | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59406679; called by muse, mutect2, varscan2
- COL21A1 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779481; called by muse, mutect2, varscan2
- COL28A1 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755623661, COSV68084331; called by muse, mutect2, varscan2
- COL28A1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV68084332; called by muse, mutect2, varscan2
- COL2A1 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1178264170, COSV61532745, COSV61533833; called by muse, mutect2, varscan2
- COL3A1 | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1512414, COSV58595752; called by muse, mutect2, varscan2
- COL4A4 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61629944; called by muse, varscan2
- COL5A3 | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53418339; called by muse, mutect2, varscan2
- COL5A3 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.452); catalogued as rs373155063; called by muse, mutect2, varscan2
- COL6A3 | c.6616C>T p.P2206S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55107243; called by muse, mutect2, varscan2
- COL6A6 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV62034379; called by muse, mutect2, varscan2
- COL7A1 | c.5293C>T p.P1765S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.613); catalogued as rs1053716176, COSV60402381; called by muse, mutect2, varscan2
- CORIN | c.2562G>A p.W854* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV56698510, COSV99904374; called by muse, mutect2, varscan2
- CPAMD8 | c.2771C>T p.S924F (on ENST00000651564; = p.S877F on NM_015692.5) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV101488546; called by muse, mutect2, varscan2
- CPN2 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV60471646; called by muse, mutect2, varscan2
- CPPED1 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as rs752496637, COSV55501009; called by muse, mutect2, varscan2
- CR2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs746224290, COSV65509489; called by muse, mutect2, varscan2
- CRB1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.935); catalogued as rs1314024688, COSV66329773; called by muse, mutect2, varscan2
- CRISP2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV59253357; called by muse, mutect2, varscan2
- CRP | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV54814552; called by muse, mutect2, varscan2
- CRYGB | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757866285, COSV53681033; called by muse, mutect2, varscan2
- CRYZL1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51679484; called by muse, mutect2, varscan2
- CSHL1 | c.289G>A p.E97K (on ENST00000309894 / NM_022581.3; = p.E3K on NM_001318.4) | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs1240202107, COSV51989877; called by muse, mutect2, varscan2
- CSMD1 | c.3500C>T p.S1167F (on ENST00000520002; = p.S1166F on NM_033225.6) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59377264; called by muse, mutect2, varscan2
- CSMD2 | c.9479A>T p.K3160I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV53957082; called by mutect2, varscan2
- CSMD2 | c.4234G>A p.D1412N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as COSV53957144; called by muse, varscan2
- CSMD2 | c.4190G>T p.S1397I | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV53957169; called by muse, varscan2
- CSMD3 | c.9958C>T p.P3320S (on ENST00000297405 / NM_001363185.1; = p.P3151S on NM_052900.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV52271134; called by muse, mutect2, varscan2
- CSMD3 | c.2231A>T p.N744I (on ENST00000297405 / NM_001363185.1; = p.N640I on NM_052900.3) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52304057; called by muse, mutect2, varscan2
- CTAGE15 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs757722933, COSV69481949; called by mutect2, varscan2
- CTNNA2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs766350655, COSV63546883; called by muse, mutect2, varscan2
- CTNNA3 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747068282, COSV65616438; called by muse, mutect2, varscan2
- CTNND1 | c.1939C>T p.P647S (on ENST00000399050 / NM_001085458.2; = p.P641S on NM_001331.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62385940; called by muse, mutect2, varscan2
- CTNND2 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV58871653; called by mutect2, varscan2
- CUBN | c.3745C>T p.R1249C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs368224687; called by mutect2, varscan2
- CUL5 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as rs138143013; called by muse, mutect2, varscan2
- CUX1 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52891670; called by muse, varscan2
- CUX1 | c.1747C>T p.Q583* | Nonsense Mutation (SNP) | VAF 38/144 reads (26%) | catalogued as COSV52913709; called by muse, varscan2
- CYP2A13 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1407668557, COSV100386997, COSV57839888; called by muse, mutect2, varscan2
- CYP2A7 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs549997563, COSV52506016; called by muse, mutect2, varscan2
- CYP2C9 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs530507053, COSV99582951; called by muse, mutect2, varscan2
- CYP2C9 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1207174374, COSV53247711; called by muse, mutect2
- CYP2E1 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV53315170; called by muse, mutect2, varscan2
- CYP3A4 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as COSV60504013; called by muse, varscan2
- CYP4F12 | c.648G>A p.E216= | Splice Region (SNP) | VAF 24/87 reads (28%) | catalogued as rs1438574883, COSV100215969, COSV61176757; called by muse, mutect2, varscan2
- CYP8B1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV60227551; called by muse, mutect2, varscan2
- CYTIP | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as rs769091432, COSV51634836; called by muse, mutect2, varscan2
- DAB1 | c.1348G>A p.D450N (on ENST00000371231; = p.D417N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV64690418; called by muse, mutect2, varscan2
- DACH1 | c.1427C>T p.P476L (on ENST00000619232 / NM_001366712.1; = p.P424L on NM_080759.6) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.042); catalogued as COSV57518177; called by muse, mutect2, varscan2
- DBNDD1 | c.266C>T p.A89V (on ENST00000002501 / NM_001042610.3; = p.A109V on NM_024043.3) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV50021983; called by muse, mutect2, varscan2
- DCTN1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.956); catalogued as COSV62621413; called by muse, mutect2, varscan2
- DDX17 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53256174; called by muse, mutect2, varscan2
- DEFA5 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs868009698, COSV57962540; called by muse, mutect2, varscan2
- DEFB110 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs771539908, COSV64484523; called by muse, mutect2, varscan2
- DGKQ | c.2305T>C p.F769L | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53281042; called by muse, mutect2, varscan2
- DHRS7C | c.413A>G p.K138R (on ENST00000330255 / NM_001220493.2; = p.K137R on NM_001105571.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV57652599; called by muse, mutect2, varscan2
- DHTKD1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53806609; called by muse, mutect2
- DHTKD1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53806619; called by muse, mutect2
- DHX29 | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV52421726; called by muse, mutect2, varscan2
- DHX34 | c.2708C>T p.S903F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV60894546; called by muse, mutect2, varscan2
- DICER1 | c.5606C>T p.P1869L | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1459884777, COSV100602315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.5605C>T p.P1869S | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100602317, COSV58623370; called by muse, mutect2, varscan2
- DIP2C | c.2569C>T p.Q857* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55154956; called by mutect2, varscan2
- DISP3 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV53836473; called by muse, mutect2, varscan2
- DLL1 | c.1835T>C p.I612T | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV64538695; called by muse, mutect2, varscan2
- DLX1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.084); catalogued as COSV59395196; called by muse, mutect2, varscan2
- DMBX1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV63602556; called by muse, mutect2, varscan2
- DMBX1 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV63602561; called by muse, mutect2, varscan2
- DMRTB1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); catalogued as rs1319032732, COSV65113944; called by muse, mutect2, varscan2
- DMTF1 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57539272; called by muse, mutect2, varscan2
- DNAH3 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as rs774996202, COSV54548360; called by muse, mutect2, varscan2
- DNAH5 | c.12424C>T p.L4142F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); catalogued as COSV54249131; called by muse, mutect2, varscan2
- DNAH5 | c.11668G>A p.E3890K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV54249141; called by muse, mutect2, varscan2
- DNAH5 | c.10257A>G p.I3419M | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54249150; called by muse, mutect2, varscan2
- DNAH5 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs560939419, COSV54203651, COSV99453001; called by muse, mutect2, varscan2
- DNAH5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs757056449, CM150542, COSV54237241; called by muse, mutect2, varscan2
- DNAH7 | c.5765G>A p.G1922E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV56758834; called by muse, mutect2, varscan2
- DNAH8 | c.4415A>T p.K1472I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV59477143; called by mutect2, varscan2
- DNAH8 | c.5579G>A p.G1860E | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs989332520, COSV59477165; called by muse, mutect2, varscan2
- DNAH8 | c.7716G>A p.M2572I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321513367, COSV59448576; called by muse, mutect2, varscan2
- DNAH8 | c.9259G>A p.D3087N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV59477220; called by muse, mutect2, varscan2
- DNAH8 | c.10952G>A p.R3651Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs1250983135, COSV59437400; called by muse, varscan2
- DNAH9 | c.8875G>A p.G2959R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52374475; called by muse, varscan2
- DNM3 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1316810940, COSV62466258; called by muse, mutect2, varscan2
- DOCK2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953545; called by muse, mutect2
- DOCK5 | c.4045T>C p.Y1349H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV52410450; called by muse, mutect2, varscan2
- DOP1A | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV52717319; called by mutect2, varscan2
- DPPA5 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV64875969; called by muse, mutect2, varscan2
- DPYD | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64612983, COSV64613125, COSV64615120; called by muse, mutect2, varscan2
- DPYSL3 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs1429252383, COSV58330644; called by muse, mutect2, varscan2
- DSC1 | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57150944; called by muse, mutect2, varscan2
- DSCAM | c.5633C>T p.P1878L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68026857; called by muse, varscan2
- DSE | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs762120249, COSV59063107, COSV59063648; called by muse, mutect2, varscan2
- DSEL | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59494361; called by muse, mutect2, varscan2
- DSP | c.3688G>A p.D1230N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as COSV65795524; called by muse, mutect2, varscan2
- DST | c.7495C>T p.P2499S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1452454213, COSV55051457; called by muse, mutect2, varscan2
- DYNC2I2 | c.1313T>A p.L438Q | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63989640; called by muse, mutect2, varscan2
- E2F7 | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs368715946; called by mutect2, varscan2
- ECEL1 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100458867; called by mutect2, varscan2
- ECHDC2 | c.713C>T p.A238V (on ENST00000371522 / NM_001198961.2; = p.A207V on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64302201; called by muse, mutect2, varscan2
- EEF2 | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV58580831; called by muse, mutect2, varscan2
- EGF | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54484028; called by muse, mutect2, varscan2
- EGFLAM | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs868108020, COSV59309866; called by muse, mutect2, varscan2
- EIF2B3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64518597; called by muse, mutect2, varscan2
- EIF2B3 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV64518601; called by muse, mutect2, varscan2
- ELOVL7 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70918650; called by muse, mutect2, varscan2
- ENAM | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV68535871; called by muse, mutect2, varscan2
- EPAS1 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751622129, COSV55390019; called by muse, mutect2, varscan2
- EPB41L2 | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61358698; called by muse, mutect2, varscan2
- EPB41L2 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs547603639, COSV61358702; called by muse, mutect2, varscan2
- EPHA3 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV60699564, COSV60725267; called by muse, varscan2
- EPHA3 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV60694465, COSV60714244, COSV60727966; called by muse, varscan2
- EPHB6 | c.1346G>C p.G449A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.059); catalogued as COSV67418276, COSV67420613; called by muse, mutect2, varscan2
- EPPK1 | c.4759A>G p.I1587V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV73262332; called by muse, mutect2, varscan2
- ERBB4 | c.3380G>A p.R1127K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV61519362; called by muse, mutect2, varscan2
- ERC2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs747730160, COSV55605679; called by muse, mutect2, varscan2
- ERCC6 | c.2219C>T p.P740L | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63393990; called by muse, mutect2, varscan2
- ESF1 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52523974; called by muse, mutect2, varscan2
- ESRP2 | c.1379C>T p.P460L (on ENST00000565858 / NM_001365264.1; = p.P450L on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs759779188, COSV52175924, COSV99251245; called by mutect2, varscan2
- ESYT3 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs775152608, COSV56680361; called by muse, varscan2
- ESYT3 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs199999624, COSV56681795; called by muse, varscan2
- ETHE1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768669208, COSV52679397; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by mutect2, varscan2
- ETS2 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV62874235; called by muse, mutect2, varscan2
- ETV5 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV60506181; called by muse, mutect2, varscan2
- EVC2 | c.2221C>T p.L741F | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV60401706; called by muse, mutect2, varscan2
- EXD3 | c.238A>T p.I80F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV59813012; called by muse, mutect2, varscan2
- EXO5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as rs766649037, COSV56416715; called by muse, mutect2, varscan2
- F12 | c.1568A>G p.Q523R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.158); catalogued as rs763312494, COSV53692947, COSV99499944; called by muse, varscan2
- FAF1 | c.1057T>A p.F353I | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV65643468; called by mutect2, varscan2
- FAIM2 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV57740964; called by muse, mutect2, varscan2
- FAM135B | c.4035G>A p.M1345I | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52705063; called by muse, mutect2, varscan2
- FAM166A | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV61115455; called by muse, mutect2, varscan2
- FAM193A | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 124/455 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as rs1365985210, COSV61198325; called by muse, mutect2, varscan2
- FAM200A | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1200484901, COSV101282736; called by muse, mutect2, varscan2
- FAM71A | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54237100; called by muse, mutect2, varscan2
- FAN1 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV62951988; called by muse, mutect2, varscan2
- FANCI | c.3359C>T p.S1120F (on ENST00000310775 / NM_001376911.1; = p.S1060F on NM_018193.3) | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV55534052; called by muse, mutect2, varscan2
- FAS | c.444-1G>A p.X148_splice | Splice Site (SNP) | VAF 4/9 reads (44%) | catalogued as CS991510, COSV100570876, COSV58239475, COSV58240007; called by muse, mutect2, varscan2
- FASN | c.6157C>T p.L2053F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs770753805, COSV100148095; called by muse, mutect2, varscan2
- FAT2 | c.2195C>A p.T732N | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs749857465, COSV55818326, COSV55828556; called by muse, mutect2, varscan2
- FAT3 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs756001256, COSV53081676; called by muse, mutect2, varscan2
- FBLN2 | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319398671, COSV55490440; called by muse, varscan2
- FBXO34 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs1324012875, COSV58256783; called by muse, mutect2, varscan2
- FBXO42 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV65046139; called by muse, mutect2
- FER1L6 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV67552566; called by muse, mutect2, varscan2
- FGD6 | c.3508G>T p.E1170* | Nonsense Mutation (SNP) | VAF 57/137 reads (42%) | catalogued as COSV59696766; called by muse, mutect2, varscan2
- FGF4 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51450649; called by mutect2, varscan2
- FGFR2 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV60658074; called by muse, mutect2, varscan2
- FILIP1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV52739916; called by muse, varscan2
- FKRP | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV59360093; called by muse, mutect2, varscan2
- FLG | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.07); catalogued as COSV64242516, COSV64248152; called by muse, mutect2, varscan2
- FMNL1 | c.3284G>A p.G1095E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.532); catalogued as COSV58958979; called by muse, mutect2, varscan2
- FMO1 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV61447612; called by muse, mutect2, varscan2
- FNDC1 | c.5228C>T p.P1743L | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51947097; called by muse, mutect2, varscan2
- FNIP2 | c.2833C>T p.R945C | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756311041, COSV52445235; called by muse, mutect2, varscan2
- FOXG1 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV57399268; called by muse, mutect2, varscan2
- FOXN1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as rs1026597581, COSV56884035; called by muse, mutect2, varscan2
- FOXP1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs1358353721, COSV59520546; called by muse, mutect2, varscan2
- FREM1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV66525113; called by muse, varscan2
- FREM2 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV54842566; called by muse, mutect2, varscan2
- FSHR | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1251961623, COSV100437240, COSV58633933; called by muse, mutect2, varscan2
- FUT1 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59569895; called by muse, mutect2, varscan2
- FUT1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV59569907; called by muse, mutect2, varscan2
- GABRB1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as rs1255847912, COSV54974161; called by mutect2, varscan2
- GABRQ | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 88/114 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs1556820516, COSV100941404, COSV64783731; called by muse, varscan2
- GAL3ST1 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58893512; called by muse, varscan2
- GALNT13 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101223923, COSV67237145; called by muse, mutect2, varscan2
- GATB | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV56133235; called by muse, mutect2, varscan2
- GCK | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as CM012121, BM1487379, COSV60787990; called by muse, mutect2, varscan2
- GCOM1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as COSV51093995, COSV51096943; called by muse, mutect2, varscan2
- GDF15 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs1404100401, COSV53251705; called by muse, mutect2, varscan2
- GH2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757832053, COSV60427734; called by muse, mutect2, varscan2
- GHDC | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1472737257, COSV56989689; called by muse, mutect2
- GINS4 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV104372066, COSV52530941; called by muse, mutect2, varscan2
- GLCE | c.1815G>A p.W605* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as COSV55948163; called by mutect2, varscan2
- GLIS3 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV60935468; called by muse, varscan2
- GLRX3 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs1301359883, COSV100487945; called by muse, mutect2, varscan2
- GLTPD2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV58702941; called by muse, mutect2, varscan2
- GLYATL1 | c.226C>T p.R76C (on ENST00000317391 / NM_001354699.1; = p.R107C on NM_080661.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs151204927, COSV55607318; called by mutect2, varscan2
- GLYATL2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as rs950923423, COSV54849193; called by muse, mutect2, varscan2
- GPATCH8 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.631); catalogued as COSV100132746; called by muse, mutect2, varscan2
- GPI | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as COSV62894818; called by muse, mutect2, varscan2
- GPR137 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as COSV57403787; called by muse, mutect2, varscan2
- GPR152 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV56887955; called by muse, mutect2, varscan2
- GPR32 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54515447; called by muse, mutect2, varscan2
- GPRIN2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV65402504; called by muse, mutect2, varscan2
- GRIA1 | c.1594C>T p.L532F | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53622342; called by muse, varscan2
- GRIN2A | c.3199C>T p.R1067W | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58021247; called by muse, mutect2, varscan2
- GRIN2B | c.4391C>T p.A1464V | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV74207575; called by muse, mutect2, varscan2
- GRM6 | c.1897C>T p.L633F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51449009; called by muse, mutect2, varscan2
- GSAP | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs193205180, COSV57530344; called by muse, mutect2, varscan2
- GSS | c.1302-1G>A p.X434_splice | Splice Site (SNP) | VAF 24/57 reads (42%) | catalogued as COSV99404523; called by muse, mutect2, varscan2
- GTDC1 | c.646A>C p.K216Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV54005342; called by muse, mutect2, varscan2
- GTF2H1 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56380115; called by muse, mutect2, varscan2
- GTPBP2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61077286; called by muse, mutect2
- GUCY2F | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 153/230 reads (67%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs773038894, COSV54304654; called by muse, mutect2, varscan2
- GYS1 | c.1666C>G p.R556G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV54405168; called by muse, mutect2, varscan2
- GZMA | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as COSV57114328; called by muse, mutect2, varscan2
- H3-5 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as rs1288725636, COSV61188151; called by muse, mutect2, varscan2
- HABP2 | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100668020; called by muse, mutect2
- HADHA | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV66108582; called by muse, mutect2, varscan2
- HAPLN1 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as rs1434710716, COSV57151631; called by muse, mutect2, varscan2
- HCN1 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV57520513; called by muse, mutect2, varscan2
- HCRTR2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as rs866211132, COSV63794599, COSV63798832; called by muse, mutect2, varscan2
- HECW2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53672935; called by muse, mutect2, varscan2
- HEG1 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV60761823; called by muse, mutect2, varscan2
- HEPACAM | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53432267; called by muse, varscan2
- HEPH | c.1268G>A p.R423Q (on ENST00000343002; = p.R156Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs748869673, COSV57958937; called by muse, mutect2, varscan2
- HERC2 | c.12875C>T p.P4292L | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55347874; called by muse, varscan2
- HHATL | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100124541; called by muse, mutect2, varscan2
- HHATL | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1280573904, COSV100124542; called by muse, mutect2, varscan2
- HHIPL2 | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 103/522 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58567535; called by muse, mutect2, varscan2
- HIVEP1 | c.3092G>A p.R1031K | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65104740; called by muse, mutect2, varscan2
- HLA-B | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV69520511, COSV69520518, COSV69520892; called by muse, varscan2
- HNRNPK | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV61090920; called by muse, mutect2, varscan2
- HPD | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56641951; called by muse, mutect2, varscan2
- HS6ST3 | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.191); catalogued as COSV65003488; called by muse, mutect2
- HSF2 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV63774503; called by muse, mutect2, varscan2
- HSF2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV63774507; called by muse, mutect2, varscan2
- HSP90B1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV55357670; called by muse, mutect2, varscan2
- HSPG2 | c.8159C>T p.P2720L | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as rs755296142, COSV65973560; called by muse, mutect2, varscan2
- HTR3B | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs1299902785, COSV52747442; called by muse, mutect2, varscan2
- ICOS | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV57031035; called by muse, mutect2, varscan2
- IDO2 | c.385G>A p.V129I (on ENST00000389060; = p.V142I on NM_194294.2) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs555940566, COSV100584871; called by muse, mutect2, varscan2
- IFIT2 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs543713702, COSV51080522; called by muse, mutect2, varscan2
- IFNAR2 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775107055, COSV51617853; called by muse, mutect2, varscan2
- IFT27 | c.392G>A p.R131Q (on ENST00000433985 / NM_001363003.2; = p.R130Q on NM_006860.5) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs551959746, COSV61416868; called by muse, mutect2, varscan2
- IGFN1 | c.2356G>A p.G786R (on ENST00000295591 / NM_001367841.1; = p.G3243R on NM_001164586.2) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1237855905, COSV55183628; called by muse, mutect2, varscan2
- IGHG2 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs1255017475; called by muse, varscan2
- IGHV1-24 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 49/237 reads (21%) | catalogued as rs781857259; called by muse, mutect2, varscan2
- IGKV3-20 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1161434479; called by muse, mutect2, varscan2
- IGSF10 | c.5378G>A p.G1793E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.33); catalogued as COSV56791077; called by muse, mutect2, varscan2
- IL21R | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs149169230; called by muse, mutect2, varscan2
- IL37 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs145730208, COSV54492103; called by mutect2, varscan2
- IL37 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54490299; called by muse, mutect2, varscan2
- ILDR1 | c.1379G>A p.G460E (on ENST00000344209 / NM_001199799.2; = p.G416E on NM_175924.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs760017535, COSV56553535; called by muse, mutect2, varscan2
- IMPG2 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51985053; called by muse, mutect2, varscan2
- INTS8 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 222/723 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.675); catalogued as COSV58253063; called by muse, mutect2, varscan2
- IQGAP3 | c.4663C>T p.P1555S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs746360155, COSV63254361; called by muse, mutect2, varscan2
- IQSEC3 | c.3056C>T p.S1019L (on ENST00000538872 / NM_001170738.2; = p.S716L on NM_015232.1) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as rs1555099494, COSV58283305; called by mutect2, varscan2
- ISOC2 | c.370G>A p.D124N (on ENST00000425675 / NM_001136201.2; = p.D140N on NM_024710.3) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.762); catalogued as COSV50035362; called by muse, varscan2
- ITGA7 | c.2705C>T p.S902F (on ENST00000555728; = p.S858F on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57700563; called by muse, mutect2, varscan2
- ITGB6 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51798224; called by muse, mutect2, varscan2
- ITIH5 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.3); catalogued as rs780892784, COSV53673077; called by mutect2, varscan2
- ITIH6 | c.2533C>T p.L845F | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV54494064; called by muse, mutect2, varscan2
- IYD | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); catalogued as rs777194249, COSV57604315; called by muse, mutect2, varscan2
- JAK3 | c.3326C>T p.A1109V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); catalogued as rs1419169817, COSV71687510; called by muse, mutect2, varscan2
- KANK4 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1354584777, COSV62989088; called by muse, varscan2
- KAT6B | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as COSV54753921; called by muse, mutect2, varscan2
- KCNAB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV67489909; called by muse, mutect2, varscan2
- KCNB2 | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 8/153 reads (5%) | catalogued as COSV73052739; called by muse, mutect2
- KCNB2 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV101578879; called by muse, mutect2, varscan2
- KCNH5 | c.2092C>T p.L698F | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59776055; called by muse, mutect2, varscan2
- KCNH7 | c.3005C>T p.P1002L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1400936639, COSV59811983; called by muse, varscan2
- KCNIP4 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100749724, COSV62856760; called by muse, mutect2, varscan2
- KCNK13 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56414507; called by muse, mutect2, varscan2
- KCNK18 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs3026042, COSV57971014, COSV57973091, COSV57973363; called by muse, mutect2, varscan2
- KCNQ5 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs753499398, COSV59655593; called by muse, mutect2, varscan2
- KCNT2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54106340; called by muse, mutect2
- KDM4D | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58636307; called by muse, mutect2, varscan2
- KDM5B | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757818490, COSV52506816; called by muse, mutect2, varscan2
- KDM6B | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54686435; called by muse, mutect2, varscan2
- KDR | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868047715, COSV55764136; called by muse, mutect2, varscan2
- KEL | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV62334527; called by muse, mutect2, varscan2
- KHDC3L | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV64869731; called by muse, mutect2, varscan2
- KIAA0895 | c.1348C>T p.Q450* (on ENST00000297063 / NM_001100425.2; = p.Q399* on NM_015314.3) | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV51713761; called by muse, mutect2, varscan2
- KIAA1549 | c.2563A>G p.T855A | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1195330485, COSV54327007; called by muse, mutect2, varscan2
- KIAA1841 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV54373563; called by muse, mutect2, varscan2
- KIF13A | c.4462C>T p.L1488F | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV52464510; called by muse, mutect2, varscan2
- KIF19 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63430502; called by muse, mutect2, varscan2
- KIF1C | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV57907146; called by muse, mutect2, varscan2
- KIF4B | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV70528455, COSV70529222; called by muse, mutect2, varscan2
- KIF6 | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54692703; called by muse, mutect2, varscan2
- KIFC1 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.083); catalogued as COSV65737886; called by muse, mutect2, varscan2
- KIR3DL1 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs1460005083, COSV58495716; called by muse, mutect2, varscan2
- KLC4 | c.1663C>T p.L555F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV52439020, COSV99432754; called by muse, varscan2
- KLK8 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as rs1332741543, COSV51594392; called by muse, mutect2, varscan2
- KMO | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100844809; called by muse, mutect2, varscan2
- KMT2A | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 27/44 reads (61%) | catalogued as COSV63282042; called by muse, mutect2, varscan2
- KMT2B | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs752388943, COSV52892371; called by muse, mutect2, varscan2
- KMT2B | c.4003G>A p.G1335R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55868040; called by muse, mutect2, varscan2
- KNL1 | c.6199A>T p.K2067* (on ENST00000346991 / NM_170589.5; = p.K2041* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 50/198 reads (25%) | catalogued as COSV61159900; called by mutect2, varscan2
- KPNA6 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1324183850, COSV65359494; called by muse, mutect2, varscan2
- KPRP | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs981583565, COSV100908728, COSV64222894; called by muse, mutect2, varscan2
- KRI1 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV57265817; called by muse, mutect2, varscan2
- KRT12 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV52432335; called by muse, mutect2, varscan2
- KRT72 | c.639G>A p.K213= | Splice Region (SNP) | VAF 25/98 reads (26%) | catalogued as rs201576778, COSV53376641; called by muse, mutect2, varscan2
- KRT74 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV59771237; called by muse, mutect2, varscan2
- KRT75 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52874629; called by mutect2, varscan2
- KRT78 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs961381634, COSV58853427; called by muse, mutect2, varscan2
- KRT80 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57551384; called by muse, mutect2, varscan2
- L3MBTL1 | c.1543G>A p.E515K (on ENST00000418998 / NM_001377303.1; = p.E425K on NM_015478.7) | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64229581; called by muse, mutect2, varscan2
- L3MBTL4 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53116007; called by muse, varscan2
- LAG3 | c.758T>G p.I253S | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV52569205; called by muse, mutect2, varscan2
- LANCL2 | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as COSV54652287; called by muse, mutect2, varscan2
- LARP4B | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV60223657; called by muse, mutect2, varscan2
- LEPR | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs56117117, COSV62750685; called by muse, mutect2, varscan2
- LGALS4 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57043252, COSV57044961; called by muse, mutect2, varscan2
- LGR6 | c.2173G>A p.G725S (on ENST00000367278 / NM_001017403.1; = p.G673S on NM_021636.3) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV55164094, COSV55165573; called by muse, mutect2, varscan2
- LHCGR | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.532); catalogued as rs776172758, COSV54291945; called by muse, mutect2, varscan2
- LHX4 | c.672G>C p.W224C | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55377860; called by muse, mutect2, varscan2
- LIG1 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV99619135; called by mutect2, varscan2
- LILRA1 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs1307078996, COSV52184549; called by muse, mutect2, varscan2
- LILRA4 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as COSV52490042, COSV52491481; called by muse, mutect2, varscan2
- LILRA4 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1385711069, COSV52490278; called by muse, mutect2, varscan2
- LILRA6 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV54433987; called by muse, mutect2, varscan2
- LILRB5 | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV60260370, COSV60260740; called by muse, varscan2
- LIPE | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV54925231; called by muse, mutect2, varscan2
- LMTK2 | c.4280C>T p.P1427L | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV52003192; called by muse, mutect2, varscan2
- LPA | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV60302742; called by muse, mutect2, varscan2
- LPAR3 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 95/269 reads (35%) | catalogued as rs1361496882, COSV65454999; called by muse, mutect2, varscan2
- LPCAT4 | c.916T>C p.F306L | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV59218792; called by muse, mutect2, varscan2
- LPIN3 | c.2155C>A p.L719I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60038530, COSV60039200; called by mutect2, varscan2
- LRIF1 | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV63898374; called by muse, mutect2, varscan2
- LRIT2 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs866647312, COSV60566106; called by muse, mutect2, varscan2
- LRP12 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs765033183, COSV52634135; called by muse, mutect2, varscan2
- LRP5 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.124); catalogued as rs1452501185, COSV53712554, COSV53713945; called by muse, mutect2, varscan2
- LRRC17 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs531608842, COSV50867556, COSV99978400; called by muse, mutect2, varscan2
- LRRFIP1 | c.1325C>T p.P442L (on ENST00000392000 / NM_001137552.2; = p.P418L on NM_004735.4) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV55256329; called by muse, mutect2, varscan2
- LSR | c.1268C>T p.P423L (on ENST00000361790; = p.P404L on NM_015925.6) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); catalogued as rs764830985, COSV55888007; called by muse, mutect2, varscan2
- LTBP1 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV63197062; called by muse, mutect2, varscan2
- LTBP1 | c.5149G>A p.D1717N (on ENST00000404816 / NM_206943.4; = p.D1391N on NM_000627.4) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV55384937, COSV99698656; called by muse, mutect2, varscan2
- LTN1 | c.3021G>A p.M1007I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs1412429427, COSV63735153; called by muse, mutect2, varscan2
- MACC1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs755419484, COSV60544418; called by muse, mutect2, varscan2
- MAEA | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53264606; called by muse, mutect2, varscan2
- MAGEA8 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV54064938; called by muse, mutect2, varscan2
- MAP2K5 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as COSV51622113; called by muse, mutect2, varscan2
- MAP2K6 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63007792; called by muse, mutect2, varscan2
- MAP3K21 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV64042498; called by muse, varscan2
- MAP3K6 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1292738208, COSV58874273; called by muse, mutect2, varscan2
- MAP4K1 | c.1200G>A p.K400= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV67712953; called by muse, mutect2, varscan2
- MAPK13 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV52983306; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as rs1381436981, COSV51726664; called by muse, mutect2, varscan2
- MAPK9 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV58125541; called by muse, mutect2, varscan2
- MDGA1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs368622840; called by mutect2, varscan2
- MDN1 | c.12472C>T p.H4158Y | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65529429; called by muse, mutect2, varscan2
- MDN1 | c.9338C>T p.S3113L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756074546, COSV65524504; called by mutect2, varscan2
- MED12L | c.1793A>G p.N598S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56395029; called by muse, varscan2
- MED13 | c.6077C>T p.S2026F | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67266736; called by muse, mutect2, varscan2
- MED15 | c.1730C>T p.S577L (on ENST00000263205 / NM_001003891.3; = p.S537L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs1461282663, COSV53031715; called by muse, mutect2, varscan2
- MEGF8 | c.5227C>T p.P1743S (on ENST00000251268 / NM_001271938.2; = p.P1676S on NM_001410.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs778172293, COSV52099887; called by mutect2, varscan2
- MGAM | c.3718C>T p.P1240S | Missense Mutation (SNP) | VAF 143/440 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs766812635, COSV72075718; called by muse, mutect2, varscan2
- MGAM | c.5423C>T p.P1808L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV72075720; called by muse, mutect2, varscan2
- MGAT5B | c.1422+1G>A p.X474_splice | Splice Site (SNP) | VAF 18/63 reads (29%) | catalogued as rs760335648, COSV100048534, COSV100048719; called by muse, mutect2, varscan2
- MGRN1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 78/284 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs1440372740, COSV52151737; called by muse, mutect2, varscan2
- MIA2 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.916); catalogued as rs1210508143, COSV99696842; called by muse, mutect2
- MICAL2 | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as COSV56315886; called by muse, mutect2, varscan2
- MIDEAS | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 40/77 reads (52%) | catalogued as COSV54098507; called by muse, mutect2, varscan2
- MKNK2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99170340; called by muse, mutect2, varscan2
- MKNK2 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99170343; called by muse, mutect2, varscan2
- MKX | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65392857; called by muse, mutect2, varscan2
- MLC1 | c.1103G>A p.W368* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV61118124; called by muse, mutect2, varscan2
- MLH3 | c.4222C>T p.H1408Y (on ENST00000355774 / NM_001040108.2; = p.H1384Y on NM_014381.3) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53158541; called by muse, mutect2, varscan2
- MLXIP | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV59837724; called by muse, mutect2, varscan2
- MMP15 | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV54681424; called by muse, mutect2, varscan2
- MOS | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV61336915; called by muse, mutect2, varscan2
- MPP6 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1285468577, COSV56040104, COSV56041744; called by muse, mutect2, varscan2
- MROH5 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.844); catalogued as COSV71302775; called by mutect2, varscan2
- MROH7 | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59877135; called by muse, mutect2, varscan2
- MRPS14 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as rs749935224, COSV62880653, COSV62880737; called by muse, mutect2, varscan2
- MSTN | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53622020; called by muse, mutect2, varscan2
- MTCL1 | c.5233C>T p.R1745C (on ENST00000306329 / NM_001378206.1; = p.R1426C on NM_015210.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60411317; called by muse, mutect2, varscan2
- MTMR7 | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV51670059; called by muse, mutect2, varscan2
- MTSS2 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99851931; called by muse, mutect2, varscan2
- MTUS2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV70921982; called by muse, mutect2, varscan2
- MUC16 | c.41045C>T p.P13682L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV101110103, COSV66696062; called by muse, mutect2, varscan2
- MUC16 | c.35583G>A p.M11861I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs754483495, COSV67456054; called by muse, mutect2, varscan2
- MUC16 | c.35105C>T p.S11702F | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.181); catalogued as COSV67465435, COSV67476127; called by muse, mutect2, varscan2
- MUC16 | c.32882C>T p.T10961I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as rs768460322, COSV67490359; called by muse, varscan2
- MUC16 | c.17764G>A p.E5922K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV67451764; called by muse, mutect2, varscan2
- MUC16 | c.12533C>T p.S4178L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV67490379; called by muse, mutect2, varscan2
- MUC16 | c.8890G>A p.G2964R | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.082); catalogued as COSV67477605, COSV67492095; called by muse, mutect2, varscan2
- MUC16 | c.3064C>T p.L1022F | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs370464728; called by muse, mutect2, varscan2
- MUC16 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs868042191, COSV67490388; called by muse, mutect2
- MUC17 | c.5540C>T p.S1847L | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as rs1315933138, COSV60302122; called by muse, mutect2, varscan2
- MUC17 | c.12808G>A p.E4270K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.039); catalogued as rs200201977; called by muse, mutect2, varscan2
- MUC3A | c.8367G>A p.M2789I | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.015); catalogued as COSV60224054; called by muse, varscan2
- MX1 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV55820759; called by muse, mutect2
- MXD1 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100037560; called by muse, mutect2, varscan2
- MXRA5 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54248767; called by muse, mutect2, varscan2
- MXRA5 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV54237368; called by muse, mutect2, varscan2
- MYBPC3 | c.2852G>A p.G951E | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57033102; called by muse, mutect2, varscan2
- MYF6 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565862303, COSV57353165; called by muse, mutect2, varscan2
- MYH8 | c.5408C>T p.A1803V | Missense Mutation (SNP) | VAF 77/122 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67971623; called by muse, mutect2, varscan2
- MYH8 | c.537C>T p.I179= | Splice Region (SNP) | VAF 11/24 reads (46%) | catalogued as COSV67971628; called by muse, mutect2, varscan2
- MYO15A | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1263068319, COSV52765044; called by muse, mutect2, varscan2
- MYO18B | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV59147181; called by muse, mutect2, varscan2
- MYO5C | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | catalogued as rs760127579, COSV55904314; called by muse, mutect2, varscan2
- MYO7B | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs946882018, COSV67351508; called by muse, mutect2, varscan2
- MYOCD | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV58502875; called by muse, mutect2, varscan2
- MYOM3 | c.4246G>A p.E1416K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs369560899; called by muse, mutect2, varscan2
- MYPN | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62732298; called by mutect2, varscan2
- MYPOP | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.023); catalogued as COSV56194201, COSV56194788; called by mutect2, varscan2
- MYRF | c.1003G>A p.D335N (on ENST00000278836 / NM_001127392.3; = p.D326N on NM_013279.4) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53893593; called by muse, mutect2, varscan2
- MYT1L | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV67710462; called by muse, mutect2, varscan2
- MZF1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs754915799, COSV53043132; called by muse, varscan2
- NBEAL1 | c.6442C>T p.P2148S | Missense Mutation (SNP) | VAF 195/526 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV68917170; called by muse, mutect2, varscan2
- NCAN | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV53057730; called by muse, mutect2, varscan2
- NCAN | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.259); catalogued as rs138659174; called by muse, mutect2, varscan2
- NCAN | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53057774; called by muse, mutect2, varscan2
- NCAPD2 | c.3163C>A p.Q1055K | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV59702219; called by muse, mutect2, varscan2
- NCOA1 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV56044359, COSV99946783; called by muse, mutect2, varscan2
- NCR2 | c.380T>A p.L127Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66101262; called by muse, mutect2, varscan2
- NDFIP1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.11); catalogued as COSV54076248; called by muse, mutect2, varscan2
- NEB | c.4470G>A p.M1490I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as COSV51456601; called by muse, mutect2, varscan2
- NEFM | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs150229714; called by muse, mutect2, varscan2
- NELL1 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54319640; called by muse, mutect2, varscan2
- NEO1 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56077647; called by muse, mutect2, varscan2
- NLRP1 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as COSV52577626; called by muse, mutect2, varscan2
- NLRP11 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV64085665; called by muse, mutect2, varscan2
- NLRP11 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.9); catalogued as COSV64088250; called by muse, mutect2, varscan2
- NLRP12 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV60754436; called by muse, mutect2, varscan2
- NLRP12 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV60754454; called by muse, mutect2, varscan2
- NLRP13 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.728); catalogued as rs762522841, COSV61623609; called by muse, mutect2, varscan2
- NLRP14 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55071655; called by muse, mutect2, varscan2
- NLRP3 | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.497); catalogued as rs142624094, COSV60221894; called by muse, mutect2, varscan2
- NMS | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs552983279, COSV65259221; called by muse, mutect2, varscan2
- NOMO3 | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99530900; called by muse, mutect2, varscan2
- NOS3 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868460763, COSV52495190; called by muse, mutect2, varscan2
- NOTCH3 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99658126; called by muse, mutect2, varscan2
- NOTCH4 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 20/550 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV66679274; called by muse, mutect2
- NPAS4 | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.946); catalogued as COSV60650515; called by muse, mutect2, varscan2
- NPTX1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV60776356; called by muse, mutect2, varscan2
- NPY5R | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs766307943, COSV58451575, COSV58453144; called by muse, mutect2, varscan2
- NR1I3 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.047); catalogued as COSV63469241; called by muse, mutect2, varscan2
- NRSN1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV65893704, COSV65893793; called by muse, varscan2
- NRXN2 | c.2390-1G>A p.X797_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV55462277; called by muse, mutect2, varscan2
- NTRK1 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as COSV62328369; called by muse, mutect2, varscan2
- NUP210 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54413178; called by muse, mutect2, varscan2
- NUP210L | c.4207G>A p.G1403S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV55156695; called by muse, mutect2, varscan2
- NYAP2 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1559220989, COSV56005235; called by muse, mutect2, varscan2
- NYNRIN | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV101230646; called by muse, mutect2
- NYNRIN | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101230647; called by muse, mutect2
- OCLN | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.97); catalogued as COSV62285951; called by muse, mutect2, varscan2
- ODF3L2 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205431; called by muse, mutect2
- OGFOD3 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747310509, COSV57343026; called by muse, mutect2, varscan2
- OIT3 | c.1427T>A p.F476Y | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV61827337; called by muse, mutect2, varscan2
- OR10K1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV56873922; called by muse, mutect2, varscan2
- OR10R2 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV63768801, COSV63769462; called by muse, mutect2, varscan2
- OR10T2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57783247; called by muse, varscan2
- OR10T2 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs1026037075, COSV57783262; called by muse, varscan2
- OR13A1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV65573353; called by muse, mutect2, varscan2
- OR13C2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV73377787; called by muse, mutect2, varscan2
- OR13G1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV62945232; called by muse, mutect2, varscan2
- OR1D2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV58921697; called by muse, mutect2, varscan2
- OR1K1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV52957258; called by muse, mutect2, varscan2
- OR2A12 | c.915G>A p.W305* | Nonsense Mutation (SNP) | VAF 68/196 reads (35%) | catalogued as COSV68821065; called by muse, mutect2, varscan2
- OR2A5 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68738822, COSV68739096, COSV68739162; called by muse, mutect2, varscan2
- OR2AG2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58456120; called by muse, varscan2
- OR2M5 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV63545727; called by muse, mutect2, varscan2
- OR2T11 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as rs775686562, COSV100424942, COSV58185036, COSV58187098; called by muse, mutect2, varscan2
- OR2V2 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV60316398; called by muse, mutect2, varscan2
- OR3A1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60163754; called by muse, mutect2, varscan2
- OR4K15 | c.1000C>T p.Q334* (on ENST00000305051; = p.Q310* on NM_001005486.1) | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV59303226; called by muse, mutect2, varscan2
- OR4K17 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV100210531, COSV100210746; called by muse, mutect2, varscan2
- OR4K2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs1389547145, COSV53851400; called by muse, mutect2, varscan2
- OR4N2 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV60054625; called by muse, mutect2, varscan2
- OR4Q3 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59180196; called by mutect2, varscan2
- OR4X1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as rs772793469, COSV60723651; called by muse, mutect2, varscan2
- OR51B4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751333456, COSV66517335, COSV66517455; called by mutect2, varscan2
- OR51E2 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.748); catalogued as COSV67807096; called by muse, mutect2, varscan2
- OR51F2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59065948; called by muse, mutect2, varscan2
- OR51G2 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58992241, COSV58992948; called by muse, mutect2
- OR51M1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1010504878, COSV60783841; called by muse, mutect2, varscan2
- OR51S1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs751897505, COSV59058366; called by muse, mutect2, varscan2
- OR52K1 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56904615; called by muse, mutect2, varscan2
- OR52L1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV59989072; called by muse, mutect2, varscan2
- OR52N5 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as COSV57698514; called by muse, mutect2, varscan2
- OR5D18 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV61737788, COSV61738604; called by muse, mutect2, varscan2
- OR5L1 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61733407, COSV61735131; called by muse, mutect2, varscan2
- OR6B1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV68770610, COSV68770671; called by muse, mutect2, varscan2
- OR6C4 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1034597513, COSV67793275; called by muse, mutect2, varscan2
- OR6C68 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV65563842, COSV65563872; called by muse, mutect2, varscan2
- OR6N1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 28/186 reads (15%) | catalogued as COSV58650268; called by muse, mutect2, varscan2
- OR6N1 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV58650273; called by muse, varscan2
- OR7D2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs753509176, COSV60138781; called by muse, mutect2, varscan2
- OR7E24 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV71702348; called by muse, mutect2, varscan2
- OR8S1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV59600453; called by muse, mutect2, varscan2
- OSBPL10 | c.1810T>A p.W604R | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199691636; called by muse, mutect2, varscan2
- OSCAR | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs769223351, COSV52928497, COSV52928522; called by muse, mutect2, varscan2
- OTOF | c.3383C>T p.P1128L (on ENST00000272371 / NM_194248.3; = p.P381L on NM_004802.4) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465110068, COSV55517656; called by muse, mutect2, varscan2
- P4HA3 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV59043815; called by muse, mutect2, varscan2
- PADI2 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV64954728; called by muse, mutect2
- PAK5 | c.736T>A p.S246T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.038); catalogued as COSV62036874; called by muse, mutect2, varscan2
- PAMR1 | c.1010G>A p.G337E (on ENST00000619888 / NM_001001991.3; = p.G354E on NM_015430.4) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756521194, COSV53516112; called by muse, mutect2, varscan2
- PAPPA | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201674996, COSV60290860; called by muse, mutect2, varscan2
- PAPPA2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 111/184 reads (60%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs749013840, COSV62772467, COSV62777922; called by muse, mutect2, varscan2
- PARD3 | c.2956G>A p.D986N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV60760724; called by muse, mutect2, varscan2
- PARD3B | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV62528705; called by muse, mutect2, varscan2
- PARD3B | c.3157C>T p.P1053S (on ENST00000406610 / NM_001302769.2; = p.P984S on NM_057177.7) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.852); catalogued as COSV62528721; called by muse, mutect2, varscan2
- PARM1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100268382, COSV56653637; called by muse, mutect2, varscan2
- PARP11 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs762146923, COSV57393424; called by muse, mutect2, varscan2
- PARP14 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.122); catalogued as rs1170274922, COSV72111779; called by muse, mutect2, varscan2
- PARP15 | c.1760G>A p.G587E (on ENST00000464300 / NM_001113523.3; = p.G353E on NM_152615.2) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59972305; called by muse, mutect2, varscan2
- PARP9 | c.2342C>A p.P781H | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV64451789, COSV64452146; called by muse, mutect2, varscan2
- PASD1 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV64857463; called by muse, mutect2, varscan2
- PATZ1 | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53231130; called by muse, varscan2
- PAX5 | c.291A>T p.E97D | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV63912921; called by muse, mutect2, varscan2
- PAX8 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV54507069, COSV54511215; called by mutect2, varscan2
- PC | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as rs1368348920, COSV58922794; called by muse, mutect2, varscan2
- PCBP3 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68409883; called by muse, varscan2
- PCBP3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68409894; called by muse, varscan2
- PCDH15 | c.3418C>T p.H1140Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1457611815, COSV57385537; called by mutect2, varscan2
- PCDH19 | c.2620G>A p.E874K (on ENST00000373034 / NM_001184880.2; = p.E827K on NM_020766.3) | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.98); catalogued as COSV55270634; called by muse, mutect2, varscan2
- PCDH9 | c.2455A>G p.I819V | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.091); catalogued as rs766964204, COSV60587063; called by muse, mutect2, varscan2
- PCDHA10 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs782069130, COSV56541529; called by muse, mutect2, varscan2
- PCDHA13 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56520036, COSV56541576; called by muse, mutect2, varscan2
- PCDHA2 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1448312261, COSV65368267, COSV65368582; called by muse, mutect2, varscan2
- PCDHA6 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.056); catalogued as rs1182345858, COSV65357169; called by muse, mutect2, varscan2
- PCDHA7 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.752); catalogued as rs782422719, COSV65345501; called by muse, varscan2
- PCDHA8 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65335065, COSV65340195; called by muse, mutect2
- PCDHA8 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.653); catalogued as COSV65339198; called by muse, mutect2, varscan2
- PCDHA8 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.971); catalogued as rs1554139549, COSV65332172, COSV99061563; called by muse, mutect2
- PCDHA9 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs1313299293, COSV100969035, COSV65323556; called by muse, mutect2
- PCDHB1 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100128296; called by muse, mutect2
- PCDHB14 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as rs782388854, COSV53387102; called by mutect2, varscan2
- PCDHB2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV52031000; called by muse, mutect2, varscan2
- PCDHB2 | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV50595276; called by muse, mutect2, varscan2
- PCDHB4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.369); catalogued as COSV52026606; called by muse, mutect2, varscan2
- PCDHGA3 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs766424263, COSV54022032; called by muse, mutect2, varscan2
- PCDHGC4 | c.1493G>A p.R498K | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99341354; called by muse, mutect2, varscan2
- PCSK4 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs377093840; called by muse, mutect2, varscan2
- PCYT2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.313); catalogued as COSV58712534, COSV58713014; called by muse, mutect2, varscan2
- PDE10A | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63105394; called by muse, mutect2, varscan2
- PDE11A | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV53707110; called by muse, mutect2, varscan2
- PDE1C | c.1404G>A p.S468= | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as rs140362011, COSV58520292; called by muse, mutect2, varscan2
- PDE2A | c.2668T>C p.S890P | Missense Mutation (SNP) | VAF 74/401 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as COSV57812953; called by muse, mutect2, varscan2
- PDE3A | c.3085G>T p.D1029Y | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV62969592, COSV62981968; called by mutect2, varscan2
- PDE6B | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55330446; called by muse, mutect2, varscan2
- PDGFRL | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs755173446, COSV52414988; called by muse, varscan2
- PEG3 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55631658; called by muse, varscan2
- PELP1 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV99343146; called by muse, mutect2, varscan2
- PER2 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV54527207; called by muse, mutect2, varscan2
- PEX5 | c.1775C>T p.P592L (on ENST00000420616; = p.P584L on NM_000319.5) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV56953928; called by muse, mutect2, varscan2
- PGA3 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100337385; called by muse, varscan2
- PGLYRP3 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV51952589; called by muse, mutect2, varscan2
- PHF12 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52021912; called by muse, mutect2, varscan2
- PI4KA | c.3739C>T p.P1247S | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV55421884; called by muse, mutect2, varscan2
- PIK3AP1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs148582013; called by muse, mutect2, varscan2
- PIWIL1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1333862057, COSV55346672; called by muse, mutect2, varscan2
- PKD1L1 | c.6835C>T p.R2279C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as COSV56976848; called by muse, mutect2, varscan2
- PKD1L1 | c.6103G>A p.G2035R | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV56976856; called by muse, varscan2
- PKDREJ | c.3954T>A p.N1318K | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53552803; called by muse, mutect2, varscan2
- PKHD1L1 | c.4747A>G p.T1583A | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs886230582, COSV65751798; called by muse, mutect2, varscan2
- PKHD1L1 | c.9763G>A p.G3255R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV65751799; called by muse, varscan2
- PKP2 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV50745866; called by muse, mutect2, varscan2
- PLBD1 | c.215A>C p.N72T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV53696047; called by muse, mutect2, varscan2
- PLCB1 | c.3448T>G p.Y1150D | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV62058184, COSV62066444; called by muse, mutect2, varscan2
1,091 further variants in this file (434 protein-altering or splice-affecting, 609 silent, 48 other) are not listed here.
